Somatic mutation profile of tumor specimen TCGA-66-2793-01A (aliquot TCGA-66-2793-01A-01D-1267-08) from TCGA case TCGA-66-2793, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.8 years (25,111 days).
Specimen TCGA-66-2793-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9455c6c2-ed9d-4693-916b-6bedf57a01cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2793-11A (Solid Tissue Normal), aliquot TCGA-66-2793-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aa02790-ecf6-4453-93d2-4bf94b283668

The open-access MAF lists 330 somatic variants for this specimen: 256 protein-altering or splice-affecting, 64 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 64, Nonsense Mutation 10, Frame Shift Del 9, Splice Site 6, RNA 3, Splice Region 3, 5'UTR 2, Intron 2, 5'Flank 2, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4303G>T p.D1435Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114189, COSV52125802, COSV52127728; called by muse, mutect2, varscan2
- RYR1 | c.9310G>A p.E3104K | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as rs193922832, CM064211, COSV62099148; ClinVar: likely pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 83/97 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.396); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV70030767; called by muse, mutect2, varscan2
- ABCA4 | c.6788G>C p.R2263P | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs281865407, CM015096, COSV64670587, COSV64674040; called by muse, mutect2, varscan2
- ABRA | c.973C>G p.R325G | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV61732569; called by muse, mutect2, varscan2
- ACSM4 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as COSV68067714, COSV68067936; called by muse, mutect2, varscan2
- ACTN4 | c.2000C>A p.T667N | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV53146518; called by muse, mutect2, varscan2
- ADAD1 | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV56643947; called by muse, mutect2, varscan2
- ADAMTS20 | c.1361T>G p.F454C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67132624; called by muse, mutect2
- ADAMTS3 | c.2441A>T p.N814I | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV54393135; called by muse, mutect2, varscan2
- ADGRG7 | c.983A>T p.N328I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56297222; called by muse, mutect2, varscan2
- AKAP6 | c.2934G>C p.M978I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV55215652; called by muse, mutect2
- AMHR2 | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV57685928; called by muse, mutect2, varscan2
- ANKRD27 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV60132207; called by muse, mutect2, varscan2
- ANKRD34B | c.1204T>C p.S402P | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58613960; called by muse, mutect2, varscan2
- ANKS1A | c.1437C>A p.S479R | Missense Mutation (SNP) | VAF 143/228 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV64461132; called by muse, mutect2, varscan2
- AOX1 | c.3557A>G p.D1186G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53496159; called by muse, mutect2, varscan2
- APBA2 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV67104891; called by muse, mutect2, varscan2
- ARHGAP6 | c.564C>A p.H188Q | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV61628550; called by muse, mutect2, varscan2
- ARHGEF6 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1488710936, COSV51691653; called by muse, mutect2, varscan2
- ATAD2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761965716, COSV54881451; called by muse, mutect2, varscan2
- ATM | c.3967A>G p.K1323E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV53748106, COSV53780688; called by muse, mutect2, varscan2
- ATP11B | c.3260A>G p.D1087G | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60029242; called by muse, mutect2, varscan2
- ATP2B2 | c.1222G>A p.D408N (on ENST00000352432; = p.D374N on NM_001683.5) | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.45); catalogued as COSV59497787; called by muse, mutect2, varscan2
- BCAS1 | c.1680G>T p.L560= | Splice Region (SNP) | VAF 55/102 reads (54%) | catalogued as COSV65086626; called by muse, mutect2, varscan2
- BCL6 | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51652558; called by muse, mutect2, varscan2
- BEND3 | c.2110G>T p.D704Y | Missense Mutation (SNP) | VAF 143/260 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV64681250; called by muse, mutect2, varscan2
- BMPR1A | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100923444, COSV64406339; called by muse, mutect2, varscan2
- C2orf16 | c.3200T>A p.L1067H | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV62675984; called by muse, mutect2, varscan2
- C6orf47 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.067); catalogued as COSV63263824; called by muse, mutect2, varscan2
- CACNA1S | c.5234G>T p.R1745M | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV62940217; called by muse, mutect2, varscan2
- CALD1 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV62648457; called by muse, mutect2, varscan2
- CARMIL1 | c.3995G>T p.W1332L | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.015); catalogued as COSV61518263; called by muse, mutect2, varscan2
- CARMIL1 | c.3996G>T p.W1332C | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.302); catalogued as COSV61518271; called by muse, mutect2, varscan2
- CASR | c.2473C>G p.L825V (on ENST00000490131; = p.L902V on NM_000388.4) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV56138120; called by muse, mutect2, varscan2
- CBLL1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV56029072; called by muse, mutect2, varscan2
- CCDC121 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 145/292 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV53115120; called by muse, mutect2, varscan2
- CCDC9 | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV55721063; called by muse, mutect2, varscan2
- CCK | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV58183839; called by muse, mutect2, varscan2
- CDC42EP3 | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV54874529; called by muse, mutect2, varscan2
- CDC42EP5 | c.432C>G p.D144E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as COSV56618489; called by muse, mutect2
- CEP126 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs752186613, COSV54825816; called by muse, mutect2, varscan2
- CETN2 | c.430-2A>T p.X144_splice | Splice Site (SNP) | VAF 52/61 reads (85%) | catalogued as COSV100938624; called by muse, mutect2, varscan2
- CFAP54 | c.7277G>T p.S2426I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV61572439; called by muse, mutect2, varscan2
- CFHR2 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV66381267; called by muse, mutect2, varscan2
- CLCA2 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 51/426 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV100991325, COSV65287398; called by muse, mutect2, varscan2
- CLCA4 | c.236T>G p.L79* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as rs773085050, COSV55368525; called by muse, mutect2
- CLCN7 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); catalogued as rs748053318, COSV51970938; called by muse, mutect2
- CNGB3 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 196/475 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV60690767; called by muse, mutect2, varscan2
- COL2A1 | c.1040A>C p.D347A | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV61531166; called by muse, mutect2, varscan2
- COL9A3 | c.1511C>A p.P504Q | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58985192; called by muse, mutect2, varscan2
- CPT1A | c.90A>C p.Q30H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.717); catalogued as COSV55753227, COSV55756704; called by muse, mutect2, varscan2
- CSF2RA | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.02); catalogued as COSV62624930; called by muse, varscan2
- CUBN | c.5566A>G p.I1856V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as COSV100912417, COSV64717205; called by muse, mutect2, varscan2
- CXCR4 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV54013072; called by muse, mutect2, varscan2
- DAB2IP | c.2903G>C p.R968T (on ENST00000408936; = p.R940T on NM_032552.3) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV52260776; called by muse, mutect2, varscan2
- DCAF4L1 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 275/495 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs775882488, COSV60787458; called by muse, mutect2, varscan2
- DIP2B | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56584900; called by muse, mutect2, varscan2
- DISP2 | c.2924C>A p.A975D | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV51123928; called by muse, mutect2, varscan2
- DNAH5 | c.13502G>T p.R4501L | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54225539, COSV54229233; called by muse, mutect2, varscan2
- DNAH9 | c.11429T>C p.F3810S | Missense Mutation (SNP) | VAF 164/176 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV52352775; called by muse, mutect2, varscan2
- DRC3 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV58263710; called by muse, mutect2, varscan2
- DSCAML1 | c.5200C>A p.Q1734K (on ENST00000321322; = p.Q1674K on NM_020693.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.989); catalogued as COSV58392002; called by muse, mutect2, varscan2
- EGF | c.509+1G>A p.X170_splice | Splice Site (SNP) | VAF 11/14 reads (79%) | catalogued as COSV54479697; called by muse, mutect2, varscan2
- EML3 | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53872340; called by muse, mutect2, varscan2
- EPB41L1 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52438548, COSV52439236; called by muse, mutect2, varscan2
- EPB41L5 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as COSV55352923; called by muse, mutect2, varscan2
- EPB42 | c.585G>T p.L195F (on ENST00000441366 / NM_001114134.2; = p.L225F on NM_000119.3) | Missense Mutation (SNP) | VAF 146/261 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55750032; called by muse, mutect2, varscan2
- EXOC7 | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58742054; called by muse, mutect2, varscan2
- FBXO45 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as COSV61146638; called by muse, mutect2, varscan2
- FLNA | c.7379G>A p.G2460D (on ENST00000369850 / NM_001110556.2; = p.G2452D on NM_001456.3) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557175388, COSV61044173; called by muse, mutect2
- FLYWCH1 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV54146453; called by muse, mutect2, varscan2
- FOXP2 | c.1631A>T p.N544I | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63487130; called by muse, mutect2, varscan2
- GALNT17 | c.1012G>T p.G338C | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs761569221, COSV61164829, COSV61170298; called by muse, mutect2, varscan2
- GALNT17 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV61164833; called by muse, mutect2, varscan2
- GANAB | c.2795G>T p.G932V | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV55488902; called by muse, mutect2, varscan2
- GATA3 | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60519335; called by muse, mutect2, varscan2
- GBF1 | c.4955T>C p.M1652T (on ENST00000369983 / NM_001377137.1; = p.M1651T on NM_004193.3) | Missense Mutation (SNP) | VAF 117/137 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64145421; called by muse, mutect2, varscan2
- GFER | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 206/367 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780954807, COSV50191511; called by muse, mutect2, varscan2
- GLI4 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60682061; called by muse, mutect2, varscan2
- GRB14 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV55738696; called by muse, mutect2, varscan2
- GRIK4 | c.2207A>C p.N736T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70802712; called by muse, mutect2
- GRP | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 79/133 reads (59%) | catalogued as COSV56879724; called by muse, mutect2, varscan2
- GUCY2C | c.1789A>G p.I597V | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV53790985; called by muse, mutect2, varscan2
- GYPC | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV52146699; called by muse, mutect2, varscan2
- H3-3B | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 101/292 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV54666121; called by muse, mutect2, varscan2
- HECTD4 | c.6058C>T p.Q2020* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV66392932; called by muse, mutect2, varscan2
- HELZ2 | c.2426A>T p.E809V (on ENST00000467148 / NM_001037335.2; = p.E240V on NM_033405.3) | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV64409762; called by muse, mutect2, varscan2
- HHIPL2 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.089); catalogued as COSV58565539; called by muse, mutect2
- HIP1 | c.2953G>C p.V985L | Missense Mutation (SNP) | VAF 184/394 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61186507; called by muse, mutect2, varscan2
- HOPX | c.32A>T p.E11V (on ENST00000317745; = p.E29V on NM_032495.6) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as COSV58499895; called by muse, mutect2, varscan2
- HOXB1 | c.321C>G p.D107E | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV53317429; called by muse, mutect2, varscan2
- HSPB2 | c.463A>G p.T155A | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV57051801; called by muse, mutect2, varscan2
- IGLV2-8 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 121/162 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs745670397; called by muse, mutect2, varscan2
- INHA | c.837G>T p.W279C | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54720812; called by muse, mutect2, varscan2
- INVS | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 206/254 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52442993; called by muse, varscan2
- IPMK | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs779545983, COSV64243849; called by muse, mutect2, varscan2
- ITGAX | c.3177A>C p.I1059= | Splice Region (SNP) | VAF 6/106 reads (6%) | catalogued as COSV51646528; called by muse, mutect2
- IWS1 | c.35-1G>C p.X12_splice | Splice Site (SNP) | VAF 8/169 reads (5%) | catalogued as COSV54868907; called by muse, mutect2
- KCNG1 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65369269; called by muse, mutect2, varscan2
- KCNJ1 | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60661927; called by muse, mutect2, varscan2
- KCNK9 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs765898630, COSV57279529; called by muse, mutect2, varscan2
- KCNU1 | c.547T>C p.F183L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67756517; called by muse, mutect2, varscan2
- KHK | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV53149376; called by muse, mutect2, varscan2
- KIF15 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV58161227, COSV58163195; called by muse, mutect2
- KIFAP3 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63034416; called by muse, mutect2, varscan2
- KRT77 | c.1439A>G p.E480G | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV59239993; called by muse, mutect2, varscan2
- KRT77 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV59240002; called by muse, mutect2, varscan2
- LAMA5 | c.8420T>A p.V2807E | Missense Mutation (SNP) | VAF 145/215 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53361286; called by muse, mutect2, varscan2
- LANCL2 | c.681A>G p.V227= | Splice Region (SNP) | VAF 41/84 reads (49%) | catalogued as rs148596591; called by muse, mutect2, varscan2
- LENG8 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs745688686, COSV58728087; called by muse, mutect2, varscan2
- LHB | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs763016665, COSV55485490; called by muse, mutect2, varscan2
- LRP1B | c.13682T>A p.V4561E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs543281261, COSV67227658; called by muse, mutect2
- MEF2C | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs765658557, COSV60932027; called by muse, mutect2, varscan2
- MEIS3 | c.730G>C p.V244L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV58983739; called by muse, mutect2, varscan2
- MIPOL1 | c.1313T>G p.M438R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV59385236; called by muse, mutect2, varscan2
- MKRN3 | c.1496T>A p.L499Q | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV58810132; called by muse, mutect2, varscan2
- MTMR12 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 31/42 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53783830, COSV53784724; called by muse, mutect2, varscan2
- MTMR3 | c.2675G>A p.R892K | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.253); catalogued as rs764679608, COSV60304958; called by muse, mutect2, varscan2
- MTMR6 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67808504; called by muse, mutect2, varscan2
- MTR | c.2611A>C p.K871Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63965103; called by muse, mutect2, varscan2
- MUC16 | c.8379G>T p.Q2793H | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV67453564, COSV67470364; called by muse, mutect2, varscan2
- MYOM2 | c.4337C>T p.A1446V | Missense Mutation (SNP) | VAF 56/75 reads (75%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV50718652; called by muse, mutect2, varscan2
- NAALADL1 | c.302C>G p.T101R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV60524221; called by muse, mutect2, varscan2
- NCAN | c.365A>T p.N122I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53052112; called by muse, mutect2, varscan2
- NCOA2 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as COSV71764083; called by muse, mutect2, varscan2
- NCOR2 | c.3197C>T p.S1066F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62298968; called by muse, mutect2, varscan2
- NDST4 | c.1978A>G p.S660G | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52121718; called by muse, mutect2, varscan2
- NFIL3 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.16); catalogued as COSV52683808; called by muse, mutect2
- NLRP14 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV55067743; called by muse, mutect2, varscan2
- NLRP8 | c.2688T>A p.C896* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as COSV52588450; called by muse, mutect2, varscan2
- NMNAT3 | c.744G>C p.E248D (on ENST00000296202 / NM_001320512.1; = p.E211D on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); catalogued as COSV56154785, COSV56156653; called by muse, mutect2, varscan2
- NOS1 | c.2443G>A p.G815S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57613701; called by muse, mutect2, varscan2
- NPC1L1 | c.3437G>A p.C1146Y | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56925865; called by muse, mutect2, varscan2
- NRXN1 | c.3448G>T p.D1150Y | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58457664, COSV58465862; called by muse, mutect2, varscan2
- NUDT16 | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV63248477; called by muse, mutect2, varscan2
- NUDT6 | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52650376; called by muse, mutect2, varscan2
- NUP37 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51837956; called by muse, mutect2, varscan2
- NUTM2F | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV53556760, COSV53557909; called by muse, mutect2, varscan2
- OPLAH | c.2593G>T p.G865C | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70678168; called by muse, mutect2, varscan2
- OR10A4 | c.806C>A p.S269Y | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1564923151, COSV65842090; called by muse, mutect2, varscan2
- OR4A15 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs780246685, COSV59035571, COSV59036057; called by muse, mutect2, varscan2
- OR4D2 | c.880A>T p.M294L | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV73459780; called by muse, varscan2
- OR52W1 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV60951058; called by muse, mutect2, varscan2
- OR5B12 | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV100222489, COSV56905255; called by muse, mutect2
- OR6B1 | c.144G>C p.L48F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1176307951, COSV68770221; called by muse, mutect2, varscan2
- OR8H2 | c.236C>A p.T79K | Missense Mutation (SNP) | VAF 92/408 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV57945085; called by muse, mutect2
- OR8H2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57945089; called by muse, mutect2
- OR8K3 | c.806C>A p.T269N | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.114); catalogued as COSV57131661; called by muse, mutect2, varscan2
- OTOF | c.3769G>T p.G1257W | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55505061, COSV99718374; called by muse, mutect2, varscan2
- P2RY8 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV67177478; called by muse, mutect2, varscan2
- PAAF1 | c.1117A>C p.K373Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV60155770; called by muse, varscan2
- PAX9 | c.861G>C p.M287I | Missense Mutation (SNP) | VAF 212/378 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); catalogued as COSV58723058; called by muse, mutect2, varscan2
- PCDH11X | c.1226G>T p.R409M | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53470655; called by muse, mutect2, varscan2
- PDE11A | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53696468, COSV53706588; called by muse, mutect2, varscan2
- PDYN | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150455107; called by muse, mutect2, varscan2
- PEG3 | c.1531G>T p.G511* | Nonsense Mutation (SNP) | VAF 84/224 reads (38%) | catalogued as COSV55627901, COSV55628383; called by muse, mutect2, varscan2
- PHKG1 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.322); catalogued as COSV51916712, COSV51918144; called by muse, mutect2, varscan2
- PIK3CG | c.2391+2T>G p.X797_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV63249007; called by muse, mutect2, varscan2
- PKHD1L1 | c.11807C>T p.T3936I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65744286; called by muse, mutect2, varscan2
- PLBD2 | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as COSV55107053; called by muse, mutect2, varscan2
- PLCB1 | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV62053664; called by muse, mutect2, varscan2
- PLD4 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1247270842, COSV66915265; called by muse, mutect2
- PLEKHA3 | c.664A>T p.S222C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV52294535; called by muse, mutect2, varscan2
- PLIN1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV55583886; called by muse, mutect2, varscan2
- PLSCR4 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as COSV61608076; called by muse, mutect2, varscan2
- POM121L12 | c.202T>A p.W68R | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV68693112; called by muse, mutect2
- PPP1R13L | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100714718, COSV62908640; called by muse, mutect2, varscan2
- PRG4 | c.1595C>G p.T532S | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.205); catalogued as COSV63355669; called by muse, mutect2, varscan2
- PRIM1 | c.42A>T p.K14N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV57717468; called by muse, mutect2, varscan2
- PRKCG | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54728449; called by muse, varscan2
- PTCHD4 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV59786027; called by muse, mutect2, varscan2
- PUS7 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs1562818754, COSV62676910; called by muse, mutect2, varscan2
- PYGM | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51218138; called by muse, varscan2
- QRICH2 | c.4115A>C p.E1372A | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV53153919; called by muse, mutect2, varscan2
- RAD17 | c.146G>A p.R49K (on ENST00000380774 / NM_133339.2; = p.R38K on NM_002873.1) | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51458033, COSV51458305; called by muse, mutect2, varscan2
- RBBP6 | c.3507A>T p.K1169N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60505537; called by muse, mutect2, varscan2
- RBBP8NL | c.1533C>G p.D511E | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV53349379, COSV53350263; called by muse, mutect2, varscan2
- RFPL3 | c.656G>A p.S219N (on ENST00000249007 / NM_001098535.1; = p.S190N on NM_006604.2) | Missense Mutation (SNP) | VAF 81/91 reads (89%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV50749425; called by muse, mutect2, varscan2
- RHOH | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 67/114 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV67805807; called by muse, mutect2, varscan2
- ROR1 | c.1581G>A p.M527I | Missense Mutation (SNP) | VAF 385/594 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV64288001; called by muse, mutect2, varscan2
- RPL5 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as COSV59873549; called by muse, mutect2, varscan2
- RTKN | c.275G>T p.R92L (on ENST00000272430 / NM_001015055.2; = p.R79L on NM_033046.2) | Missense Mutation (SNP) | VAF 280/473 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.071); catalogued as rs769052248, COSV51961759, COSV51963745; called by muse, varscan2
- RTTN | c.4593G>T p.R1531S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV55345656; called by muse, mutect2, varscan2
- SCN4A | c.3254T>C p.V1085A | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV71127164; called by muse, mutect2, varscan2
- SCUBE1 | c.2732A>G p.D911G | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62612917; called by muse, mutect2, varscan2
- SERPINB4 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV61985079; called by muse, mutect2
- SHH | c.442A>C p.I148L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs745948696, COSV51918984; called by muse, mutect2, varscan2
- SHISAL2A | c.172T>A p.W58R | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68979804; called by muse, mutect2, varscan2
- SI | c.475C>G p.R159G | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV52281341, COSV52303550; called by muse, mutect2, varscan2
- SKA3 | c.395C>G p.T132S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53434989; called by muse, mutect2, varscan2
- SLC22A13 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61291190; called by muse, mutect2, varscan2
- SLC2A3 | c.1163T>C p.I388T | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs972813335, COSV50003298; called by muse, mutect2, varscan2
- SLC35C1 | c.520T>G p.C174G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58480128; called by muse, mutect2, varscan2
- SLC44A5 | c.1876G>T p.V626F | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV63766092; called by muse, mutect2, varscan2
- SLC6A13 | c.1017G>T p.M339I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV58256096, COSV58257559; called by muse, mutect2, varscan2
- SLC7A4 | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs1265485188, COSV60384247; called by muse, mutect2
- SLIT1 | c.1421A>T p.N474I | Missense Mutation (SNP) | VAF 134/162 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56590181; called by muse, mutect2, varscan2
- SLIT2 | c.3730G>T p.E1244* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV56574734; called by muse, mutect2, varscan2
- SPAG5 | c.2201G>A p.S734N | Missense Mutation (SNP) | VAF 151/186 reads (81%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV58802042; called by muse, mutect2, varscan2
- SPG11 | c.2980C>A p.L994I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV55995827; called by muse, mutect2, varscan2
- SPOPL | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54513789; called by muse, varscan2
- SPPL2C | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV61292657; called by muse, mutect2, varscan2
- SRPK1 | c.1182A>T p.E394D | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.352); catalogued as COSV60413161; called by muse, mutect2, varscan2
- SSU72P8 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV66361162; called by muse, mutect2, varscan2
- STATH | c.185T>A p.F62Y | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV55893772; called by muse, mutect2, varscan2
- SYNE1 | c.20195A>G p.Y6732C (on ENST00000367255 / NM_182961.4; = p.Y6661C on NM_033071.3) | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV54998255; called by muse, mutect2, varscan2
- TAAR2 | c.676G>T p.V226L (on ENST00000367931 / NM_001033080.1; = p.V181L on NM_014626.3) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.058); catalogued as rs1237920142, COSV51579193; called by muse, varscan2
- TENM4 | c.7202G>A p.G2401D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV53633457, COSV53652977; called by muse, mutect2, varscan2
- TET3 | c.4368G>C p.W1456C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as COSV69642970; called by muse, mutect2, varscan2
- TMEM130 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV59559465; called by muse, mutect2, varscan2
- TMEM171 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 74/99 reads (75%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV55130437; called by muse, varscan2
- TMEM63C | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 50/55 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV53604123; called by muse, mutect2, varscan2
- TOPORS | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV62117113; called by muse, mutect2, varscan2
- TRAPPC10 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 73/91 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV52377886, COSV52379111; called by muse, varscan2
- TRIM58 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV63570544, COSV99057530; called by muse, mutect2, varscan2
- TRPV5 | c.1210-2A>T p.X404_splice | Splice Site (SNP) | VAF 77/190 reads (41%) | catalogued as COSV54686485, COSV54687913; called by muse, mutect2, varscan2
- TTN | c.17334C>A p.S5778R (on ENST00000591111; = p.S4851R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | PolyPhen benign (0.1); catalogued as COSV60104336; called by muse, mutect2, varscan2
- TUBA1B | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as COSV60136557, COSV60137205; called by muse, mutect2, varscan2
- TUT7 | c.3389A>G p.N1130S | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52896070; called by muse, mutect2, varscan2
- TXLNG | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 72/75 reads (96%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV66329940; called by muse, mutect2, varscan2
- U2AF2 | c.1184A>T p.Y395F | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as COSV58274174; called by muse, mutect2, varscan2
- UNC5A | c.2270T>C p.F757S | Missense Mutation (SNP) | VAF 145/173 reads (84%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52840727; called by muse, mutect2, varscan2
- USH2A | c.10517C>A p.T3506K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56378219; called by muse, mutect2, varscan2
- USP30 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs377141587; called by muse, mutect2
- VPS13B | c.1251A>T p.K417N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62020370; called by muse, mutect2, varscan2
- WDR6 | c.2159G>C p.G720A | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV58245162; called by muse, mutect2, varscan2
- WDR62 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV53078322; called by muse, mutect2, varscan2
- WNT11 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 92/135 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1218682764, COSV59443089; called by muse, mutect2, varscan2
- WNT2 | c.663G>C p.W221C | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55411381; called by muse, mutect2, varscan2
- XPC | c.1057G>T p.V353F | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV53205335; called by muse, mutect2, varscan2
- ZEB1 | c.67T>A p.Y23N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58045596; called by muse, mutect2, varscan2
- ZFHX4 | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.131); catalogued as rs1449133037, COSV50898246; called by muse, mutect2, varscan2
- ZFHX4 | c.7274C>A p.T2425N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1270789399, COSV50899080; called by muse, mutect2
- ZNF185 | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59276250; called by muse, mutect2, varscan2
- ZNF22 | c.625C>G p.P209A | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53584107; called by muse, mutect2, varscan2
- ZNF8 | c.1248G>C p.Q416H | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV52187945; called by muse, mutect2
- ARHGAP35 | c.4335del p.G1446Afs*353 | Frame Shift Del (DEL) | VAF 81/218 reads (37%) | called by mutect2, pindel, varscan2
- ARID1A | c.3085del p.A1029Pfs*10 | Frame Shift Del (DEL) | VAF 84/108 reads (78%) | called by mutect2, pindel*, varscan2
- ASIC5 | c.290_293del p.E97Vfs*12 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- ATP4A | c.957dup p.V320Cfs*26 | Frame Shift Ins (INS) | VAF 41/114 reads (36%) | called by mutect2, pindel, varscan2
- COL4A2 | c.3319G>T p.G1107W | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.2459del p.G820Efs*13 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- H2BC8 | c.77_80del p.D26Afs*20 | Frame Shift Del (DEL) | VAF 80/262 reads (31%) | called by mutect2, pindel, varscan2
- HAUS5 | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, varscan2
- HEXA | c.454_459+24del p.X152_splice | Splice Site (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- IGKV3-7 | c.252T>A p.S84R | Missense Mutation (SNP) | VAF 100/149 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- MED15 | c.1313C>A p.P438Q (on ENST00000263205 / NM_001003891.3; = p.P398Q on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRC4 | c.1809del p.N604Ifs*69 | Frame Shift Del (DEL) | VAF 118/262 reads (45%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3493_3506del p.G1165Qfs*13 | Frame Shift Del (DEL) | VAF 28/52 reads (54%) | called by pindel, varscan2
- OPRM1 | c.21del p.T8Rfs*30 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- PIK3C2B | c.2909_2922del p.R970Pfs*17 | Frame Shift Del (DEL) | VAF 59/236 reads (25%) | called by pindel, varscan2
- TBC1D3B | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TRGC1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- ACOXL | c.336C>G p.L112= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs1436764575, COSV100489854, COSV61325633, COSV61328788; called by muse, mutect2, varscan2
- AHNAK2 | c.69G>A p.Q23= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV60917178; called by muse, mutect2, varscan2
- ASPSCR1 | c.1638G>A p.L546= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV60715810; called by muse, mutect2, varscan2
- ASTN1 | c.3543G>T p.L1181= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV62497924; called by muse, mutect2, varscan2
- BACH2 | c.951C>T p.A317= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV57594385; called by muse, mutect2, varscan2
- BAZ2B | c.1797C>G p.P599= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV58602023; called by muse, mutect2, varscan2
- BRPF1 | c.1329C>T p.Y443= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV57405255; called by muse, mutect2, varscan2
- C16orf89 | c.567G>A p.K189= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV60123712; called by muse, mutect2, varscan2
- C1orf112 | c.528T>C p.H176= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53679404; called by muse, mutect2, varscan2
- CCAR1 | c.1143A>G p.L381= | Silent (SNP) | VAF 83/186 reads (45%) | catalogued as COSV56270220; called by muse, mutect2, varscan2
- CCDC40 | c.945G>T p.V315= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV53900221; called by muse, mutect2, varscan2
- CMYA5 | c.8436G>C p.L2812= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV71406309; called by muse, mutect2, varscan2
- CNTNAP5 | c.1152C>A p.P384= | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as rs967697335, COSV70488635, COSV70505169, COSV70510848; called by muse, mutect2, varscan2
- CPED1 | c.2238C>A p.T746= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV60003615; called by muse, mutect2, varscan2
- CYP11B2 | c.424T>C p.L142= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs199988205, COSV59996175; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CYP46A1 | c.615G>T p.L205= | Silent (SNP) | VAF 91/279 reads (33%) | catalogued as COSV55894840; called by muse, mutect2, varscan2
- DLEC1 | c.369C>T p.S123= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV57300589; called by muse, mutect2
- DNAH10 | c.1470C>A p.T490= (on ENST00000409039; = p.T429= on NM_207437.3) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV68994893; called by muse, mutect2, varscan2
- FCRL3 | c.879G>T p.R293= | Silent (SNP) | VAF 77/163 reads (47%) | catalogued as COSV63841989; called by muse, mutect2, varscan2
- FES | c.66C>A p.A22= | Silent (SNP) | VAF 177/344 reads (51%) | catalogued as rs369727348, COSV51575553, COSV51577172; called by muse, varscan2
- FMO1 | c.1050C>A p.A350= | Silent (SNP) | VAF 65/127 reads (51%) | catalogued as rs866459843, COSV61446004; called by muse, mutect2, varscan2
- GPR158 | c.3390G>A p.E1130= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as rs1334018875, COSV66271574; called by muse, mutect2, varscan2
- GTF2E2 | c.390T>C p.I130= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV63478499; called by muse, mutect2, varscan2
- GUCY1A2 | c.1176T>A p.P392= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV56488457; called by muse, mutect2, varscan2
- IGSF9B | c.2559C>G p.G853= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV58068371; called by muse, mutect2
- INTS5 | c.288T>A p.P96= | Silent (SNP) | VAF 119/190 reads (63%) | catalogued as COSV100399839, COSV57951859; called by muse, mutect2, varscan2
- IRGC | c.657G>T p.S219= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as rs1441861197, COSV54984562; called by muse, mutect2, varscan2
- LHB | c.342C>T p.R114= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as COSV55485486; called by muse, mutect2, varscan2
- LPO | c.1866T>C p.G622= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV51859446; called by muse, mutect2, varscan2
- MPST | c.738C>A p.A246= (on ENST00000341116 / NM_001369904.2; = p.A266= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV62017739; called by muse, mutect2, varscan2
- MSH4 | c.2406C>T p.A802= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV54204151; called by muse, mutect2, varscan2
- MUC2 | c.1233C>T p.F411= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs373651260, COSV100363935; called by muse, mutect2, varscan2
- MYLK3 | c.453C>T p.G151= | Silent (SNP) | VAF 106/130 reads (82%) | catalogued as COSV67364583; called by muse, mutect2, varscan2
- MYO16 | c.777C>G p.L259= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV51797703, COSV99194722; called by muse, mutect2, varscan2
- NEB | c.17766C>T p.Y5922= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV51422147; called by muse, mutect2, varscan2
- NEURL1 | c.1164C>T p.R388= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV63914647; called by muse, mutect2, varscan2
- NFE2 | c.408T>A p.P136= | Silent (SNP) | VAF 59/328 reads (18%) | catalogued as COSV56456058; called by muse, mutect2, varscan2
- NR2E1 | c.366G>A p.S122= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV64562052; called by muse, mutect2, varscan2
- OR10G4 | c.174C>T p.Y58= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV100304739; called by muse, mutect2, varscan2
- PAX1 | c.1467A>C p.G489= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV68272080; called by muse, mutect2
- PCDHB2 | c.1176T>C p.P392= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs1169313640, COSV50578120; called by muse, mutect2, varscan2
- PCSK7 | c.648C>A p.P216= | Silent (SNP) | VAF 113/182 reads (62%) | catalogued as COSV58007564; called by muse, mutect2, varscan2
- PHLDB1 | c.783A>C p.P261= | Silent (SNP) | VAF 12/368 reads (3%) | catalogued as COSV61879064; called by muse, mutect2
- PI4KA | c.6291G>A p.Q2097= | Silent (SNP) | VAF 120/3898 reads (3%) | catalogued as COSV55412560; called by muse, mutect2
- PLEC | c.10872G>T p.V3624= (on ENST00000322810 / NM_201380.4; = p.V3514= on NM_000445.5) | Silent (SNP) | VAF 95/304 reads (31%) | catalogued as COSV59643230; called by muse, mutect2, varscan2
- PRPH | c.183T>C p.R61= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV57678685; called by muse, mutect2, varscan2
- PTGIR | c.753C>T p.C251= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV52192273; called by muse, mutect2, varscan2
- RAG1 | c.345G>T p.G115= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV55025653; called by muse, mutect2, varscan2
- RNF145 | c.1674A>C p.A558= (on ENST00000424310 / NM_001199383.2; = p.A586= on NM_144726.2) | Silent (SNP) | VAF 45/49 reads (92%) | catalogued as COSV50866972; called by muse, mutect2, varscan2
- RSL1D1 | c.957T>C p.D319= | Silent (SNP) | VAF 50/460 reads (11%) | catalogued as COSV63077852; called by muse, mutect2
- RYR3 | c.9703T>C p.L3235= (on ENST00000389232; = p.L3236= on NM_001036.6) | Silent (SNP) | VAF 120/215 reads (56%) | catalogued as COSV66792270; called by muse, mutect2, varscan2
- S100A10 | c.177G>A p.L59= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV64291167; called by muse, mutect2, varscan2
- SLAMF6 | c.345C>A p.T115= | Silent (SNP) | VAF 46/131 reads (35%) | catalogued as COSV63587265; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2091A>G p.V697= (on ENST00000540229 / NM_001371097.1; = p.V636= on NM_001009562.4) | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV67444536; called by muse, mutect2, varscan2
- SPTBN1 | c.2433C>G p.P811= | Silent (SNP) | VAF 33/232 reads (14%) | catalogued as COSV61689223; called by muse, mutect2, varscan2
- SRCAP | c.63G>A p.S21= | Silent (SNP) | VAF 78/185 reads (42%) | catalogued as rs755700498, COSV52673607; called by muse, mutect2, varscan2
- SRCIN1 | c.3312C>T p.P1104= (on ENST00000621492; = p.P1070= on NM_025248.3) | Silent (SNP) | VAF 61/73 reads (84%) | called by muse, mutect2, varscan2
- SSU72P8 | c.360G>T p.V120= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV66361160; called by muse, mutect2, varscan2
- STMN4 | c.177C>G p.T59= (on ENST00000265770 / NM_001283054.2; = p.T86= on NM_030795.4) | Silent (SNP) | VAF 48/217 reads (22%) | catalogued as COSV56109110, COSV56109190, COSV56109902; called by muse, mutect2, varscan2
- TMEM171 | c.9T>G p.P3= | Silent (SNP) | VAF 72/97 reads (74%) | catalogued as COSV55130427; called by muse, varscan2
- TNNT1 | c.621T>C p.S207= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs753624433, COSV52572053; called by muse, mutect2, varscan2
- UBASH3B | c.675C>A p.P225= | Silent (SNP) | VAF 137/301 reads (46%) | catalogued as COSV52495750; called by muse, mutect2, varscan2
- UNC13A | c.3417T>A p.P1139= | Silent (SNP) | VAF 63/84 reads (75%) | catalogued as COSV53197501; called by muse, mutect2, varscan2
- VPS18 | c.1557C>G p.T519= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as COSV55030560; called by muse, mutect2
- AL353804.7 | chrX:73846757 C>A | 5'Flank (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65691G>C | Intron (SNP) | VAF 161/279 reads (58%) | called by muse, mutect2, varscan2
- INSL4 | c.-2G>T | 5'UTR (SNP) | VAF 16/20 reads (80%) | catalogued as COSV53329106; called by muse, mutect2, varscan2
- LAMTOR5 | c.-59G>T | 5'UTR (SNP) | VAF 81/93 reads (87%) | catalogued as COSV56679015; called by muse, mutect2, varscan2
- MFSD11 | chr17:76736478 G>C | 5'Flank (SNP) | VAF 20/132 reads (15%) | catalogued as rs545669570, COSV57972880; called by muse, mutect2
- MIR890 | n.59C>T | RNA (SNP) | VAF 54/58 reads (93%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-2507G>C | Intron (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- OR2U1P | n.658T>A | RNA (SNP) | VAF 28/35 reads (80%) | called by muse, mutect2, varscan2
- PIGR | c.*2C>T | 3'UTR (SNP) | VAF 33/82 reads (40%) | catalogued as rs372104345; called by muse, mutect2, varscan2
- SPATA8 | n.236G>A | RNA (SNP) | VAF 41/96 reads (43%) | catalogued as COSV60704123; called by muse, varscan2
